Surgical pathology report (de-identified scan), TCGA case TCGA-06-0128, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0128-01A (Primary Tumor).

06-0128

PATHOLOGICAL DIAGNOSIS:

BRAIN, LEFT OCCIPITAL, EXCISION: HIGH HISTOLOGICAL GRADE GLIOMA (WHO GRADE IV/IV).

SEE MICROSCOPIC DESCRIPTION AND COMMENT.

ADDENDUM DIAGNOSIS: MIB-1 LABELLING INDEX: 21%.

Operation/Specimen: UPDATED REPORT - Brain, left occipital.

Clinical History and Pre-Op Dx: [REDACTED] man with ataxia and acalculia, negative past history. Cystic enhancing lesion in left occipital lobe.

GROSS PATHOLOGY: Received fresh, 2 fragments, 3 x 2 x 0.8 cm. Soft, focally, hemorrhagic, tannish-gray glistening. In total 1-5.

INTRAOPERATIVE CONSULTATION: Brain, left occipital: High histological grade glioma (C/W glioblastoma multiforme).

MICROSCOPIC: Portions of brain extensively infiltrated and focally effaced by a neoplastic proliferation of glial cells with prominent nuclear pleomorphism and anaplasia. Frequently, cells are multinucleated. There are mitotic figures, and microvascular cellular proliferation is focally prominent. There is no necrosis.

COMMENT: The lesion is a high histological grade glioma with prominent nuclear anaplasia, mitotic figures, and microvascular cellular proliferation. These are features that in the WHO classification correspond to a grade IV/IV glioma. Focally, there is suggestion of an oligodendroglial component.

ADDENDUM REPORT

IMMUNOHISTOCHEMISTRY: An immunoperoxidase method for MIB-1 was performed on sections from block #4.

A MIB-1 proliferation index of 21% was determined in the more active areas.

Source: NCI Genomic Data Commons file f59f79d2-b7f6-426e-b34c-a9ec4426f1cc (TCGA-06-0128.F782B0E3-3957-4B0E-BAED-803F0C199CE3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).